Gene-level copy-number profile of tumor specimen TCGA-CG-4301-01A from TCGA case TCGA-CG-4301, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.3 years (27,516 days).
Specimen TCGA-CG-4301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.45afe7d6-2959-4652-aecd-4cbe214dbfce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4301-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/603cc2ab-9652-407c-bad1-ddb05e825716

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 17,083; copy number 2: 37,724; copy number 3: 2,206; copy number 4: 1,731; copy number 5: 487; copy number 6: 18; copy number 8: 26; copy number 9: 149; copy number 10: 168; copy number 15: 69; copy number 17: 28; copy number 24: 51; copy number 40: 8; copy number 74: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4301-01A-01D-1155-01): tumor purity 0.42, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:60,750,575–60,796,103, 2 genes: LINC02496, AC105420.1.
- chr4:62,816,826–63,143,881, 2 genes: EXOC5P1, AC097491.1.
- chr4:92,303,966–94,757,681, 17 genes (within-gene range 0–1): GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT.
- chr18:25,818,234–29,361,963, 45 genes: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,009 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,276,768–154,539,309, 139 genes, copy number 5 (broad region; genes not listed).
- chr3:155,290,227–155,309,807, 3 genes, copy number 6 (within-gene range 1–6): STRIT1, AC104831.1, PABPC1P10.
- chr3:155,375,683–155,375,790, 1 gene, copy number 6: AC108729.3.
- chr3:180,868,141–183,163,839, 41 genes, copy number 5: FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3.
- chr3:183,253,253–183,298,504, 2 genes, copy number 5 (within-gene range 4–5): B3GNT5, RNA5SP151.
- chr7:88,759,700–89,338,528, 1 gene, copy number 5 (within-gene range 3–5): ZNF804B.
- chr7:89,443,946–96,377,920, 114 genes, copy number 5 (broad region; genes not listed).
- chr8:97,624,203–108,787,594, 211 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:113,600,310–122,733,804, 76 genes, copy number 8–17 (within-gene range 3–17) (broad region; genes not listed).
- chr12:67,929,235–73,208,317, 100 genes, copy number 5–15 (broad region; genes not listed).
- chr13:28,659,104–41,961,120, 209 genes, copy number 5–10 (broad region; genes not listed).
- chr14:22,147,995–22,482,959, 33 genes, copy number 5 (within-gene range 2–5): TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59.
- chr17:20,321,164–21,002,276, 51 genes, copy number 24 (within-gene range 1–24): CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1.
- chr17:39,637,090–39,919,854, 13 genes, copy number 40–74: STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB.
- chr20:23,547,764–23,826,729, 15 genes, copy number 5: CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2.

Autosomal genes at a single copy (total copy number 1): 15,379. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
